Somatic mutation profile of tumor specimen 0DBSCX from CCDI case PBBLSD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Craniopharyngioma, adamantinomatous; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.5 years (2,731 days).
Specimen 0DBSCX: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c59a0627-8f2d-4dd4-9f8b-01698ca17505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBSCW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b1f6748-eb13-4fac-bc19-4b806e663ee4

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 150/717 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CCDC86 | c.1039C>G p.L347V | Missense Mutation (SNP) | VAF 24/736 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as rs1400665652; called by muse, mutect2
- OR8H2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 69/1372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs868862487, COSV57943241; called by muse, mutect2
- PNPLA7 | c.2587G>T p.A863S | Missense Mutation (SNP) | VAF 26/784 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV53000473; called by muse, mutect2
- KCNK15 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 31/821 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2
- ZRANB3 | c.510C>T p.S170= | Silent (SNP) | VAF 91/944 reads (10%) | catalogued as rs774888563; called by muse, mutect2
- DUSP16 | c.*87C>T | 3'UTR (SNP) | VAF 4/54 reads (7%) | catalogued as rs1223185711; called by muse, mutect2
- MUC19 | n.6833A>C | RNA (SNP) | VAF 20/704 reads (3%) | called by muse, mutect2
